Somatic mutation profile of tumor specimen ALCH-AE0Y-TTP1-A (aliquot ALCH-AE0Y-TTP1-A-1-0-D-A612-36) from ALCHEMIST case ALCH-AE0Y, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 52.5 years (19,187 days).
Specimen ALCH-AE0Y-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74849b82-751e-475b-b05d-a2e8e0ba670d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE0Y-NB1-A (Blood Derived Normal), aliquot ALCH-AE0Y-NB1-A-1-0-D-A612-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1af40faf-2285-40e5-81b2-54f74b62fdd9

The open-access MAF lists 60 somatic variants for this specimen: 41 protein-altering or splice-affecting, 15 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 15, Intron 4, Nonsense Mutation 3, In Frame Del 2, Splice Site 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2240_2257del p.L747_P753delinsS | In Frame Del (DEL) | VAF 168/1192 reads (14%) | hotspot (GDC flag); catalogued as rs121913438, COSV51767961; ClinVar: drug response; called by mutect2, pindel
- ABCC8 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 73/706 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs956046843, COSV56859093; called by muse, mutect2, varscan2
- ARHGAP18 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV63763427; called by muse, mutect2
- CALCR | c.956G>C p.G319A (on ENST00000649521 / NM_001164737.2; = p.G303A on NM_001742.4) | Missense Mutation (SNP) | VAF 45/546 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.937); catalogued as COSV64007476; called by muse, mutect2
- CSNK1E | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as rs1209553878, COSV63290375; called by muse, mutect2, varscan2
- GAPDH | c.525+3A>G | Splice Region (SNP) | VAF 33/233 reads (14%) | catalogued as rs1279322043; called by muse, mutect2, varscan2
- GATA4 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 87/700 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs180765750; called by muse, mutect2, varscan2
- ITGAM | c.2828C>T p.T943M (on ENST00000648685 / NM_001145808.2; = p.T942M on NM_000632.4) | Missense Mutation (SNP) | VAF 45/614 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs769157570, COSV54934515; called by muse, mutect2
- LAMA2 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 34/608 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756045943, COSV70348792; called by muse, mutect2
- LRFN5 | c.1853C>T p.S618L | Missense Mutation (SNP) | VAF 45/533 reads (8%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs143897378, COSV53277569; called by muse, mutect2
- NHSL1 | c.3529G>A p.E1177K | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as rs1048362675; called by muse, mutect2
- OCA2 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 20/273 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769550106, COSV62353421, COSV62356115; called by muse, mutect2
- PRKG2 | c.1302G>A p.M434I | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100020215, COSV52331647; called by muse, mutect2, varscan2
- RIMS1 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as rs757160554; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- RUNX2 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 54/889 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs1203066173, COSV100767328; called by muse, mutect2
- STS | c.1455C>A p.F485L | Missense Mutation (SNP) | VAF 71/168 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV54267716; called by muse, mutect2, varscan2
- SYT11 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 60/760 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.147); catalogued as rs148519088, COSV64173987; called by muse, mutect2
- WDR55 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56908413; called by muse, mutect2
- WIPI1 | c.1256G>A p.G419E | Missense Mutation (SNP) | VAF 42/435 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as rs1243828704; called by muse, mutect2
- WNT16 | c.500G>A p.G167D (on ENST00000222462 / NM_057168.2; = p.G157D on NM_016087.2) | Missense Mutation (SNP) | VAF 40/856 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1218457562, COSV55974687; called by muse, mutect2
- ABCA13 | c.2150T>C p.M717T | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.146); called by muse, mutect2
- C3orf52 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 27/647 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2
- CIT | c.861G>C p.W287C | Missense Mutation (SNP) | VAF 53/451 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COG1 | c.1699C>T p.Q567* | Nonsense Mutation (SNP) | VAF 26/548 reads (5%) | called by muse, mutect2
- DHRS12 | c.596T>A p.M199K (on ENST00000444610 / NM_001377930.1; = p.M150K on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/390 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM13C | c.44G>T p.S15I | Missense Mutation (SNP) | VAF 58/774 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.273); called by muse, mutect2
- HSPG2 | c.4318A>C p.N1440H | Missense Mutation (SNP) | VAF 17/555 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KCNK13 | c.263_281del p.V88Afs*18 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | called by mutect2, pindel
- LAMA1 | c.4904G>C p.R1635T | Missense Mutation (SNP) | VAF 31/684 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.183); called by muse, mutect2
- LZTR1 | c.2181C>G p.I727M | Missense Mutation (SNP) | VAF 46/335 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO3A | c.3379A>T p.K1127* | Nonsense Mutation (SNP) | VAF 26/370 reads (7%) | called by muse, mutect2
- NFIA | c.789G>T p.R263S | Missense Mutation (SNP) | VAF 49/456 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PCSK7 | c.861-1G>C p.X287_splice | Splice Site (SNP) | VAF 17/222 reads (8%) | called by muse, mutect2
- PIM2 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 47/303 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); called by muse, varscan2
- PLSCR1 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 54/218 reads (25%) | called by muse, varscan2
- SAGE1 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 86/152 reads (57%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- SLC6A9 | c.749A>G p.N250S (on ENST00000360584 / NM_201649.4; = p.N196S on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/576 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.251); called by muse, mutect2
- SORT1 | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- STK24 | c.638A>C p.D213A | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SYT13 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 86/562 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, varscan2
- TP53 | c.740_751del p.N247_P250del | In Frame Del (DEL) | VAF 37/346 reads (11%) | called by mutect2, pindel
- AFAP1L1 | c.1557G>A p.A519= | Silent (SNP) | VAF 30/247 reads (12%) | catalogued as rs757477522, COSV57047683; called by muse, mutect2, varscan2
- C1orf226 | c.744C>T p.G248= | Silent (SNP) | VAF 23/231 reads (10%) | catalogued as rs1164680912; called by muse, mutect2, varscan2
- COL6A3 | c.1716G>A p.L572= | Silent (SNP) | VAF 35/431 reads (8%) | catalogued as rs370085973; called by muse, mutect2
- DDI1 | c.312G>A p.T104= | Silent (SNP) | VAF 33/122 reads (27%) | catalogued as rs776400594, COSV56376753; called by muse, mutect2, varscan2
- DLGAP3 | c.1059C>A p.L353= | Silent (SNP) | VAF 21/283 reads (7%) | called by muse, mutect2
- DSG4 | c.1650C>T p.I550= | Silent (SNP) | VAF 44/478 reads (9%) | called by muse, mutect2
- HDAC6 | c.762G>A p.V254= | Silent (SNP) | VAF 53/245 reads (22%) | catalogued as rs1557025042; called by muse, mutect2, varscan2
- IFT57 | c.900C>T p.I300= | Silent (SNP) | VAF 27/398 reads (7%) | called by muse, mutect2
- ITIH6 | c.2970T>C p.S990= | Silent (SNP) | VAF 11/211 reads (5%) | called by muse, mutect2
- LIG1 | c.1203C>T p.A401= | Silent (SNP) | VAF 69/263 reads (26%) | catalogued as rs1466077767; called by muse, mutect2, varscan2
- MORC1 | c.594G>A p.L198= | Silent (SNP) | VAF 15/212 reads (7%) | called by muse, mutect2
- NRG3 | c.393C>G p.T131= | Silent (SNP) | VAF 24/368 reads (7%) | called by muse, mutect2
- OR5D13 | c.162T>C p.N54= | Silent (SNP) | VAF 29/233 reads (12%) | called by muse, mutect2, varscan2
- TXLNB | c.1857C>T p.T619= | Silent (SNP) | VAF 20/134 reads (15%) | catalogued as rs762569485, COSV64445834; called by muse, mutect2, varscan2
- UQCRQ | c.135T>G p.S45= | Silent (SNP) | VAF 24/266 reads (9%) | called by muse, mutect2
- EDIL3 | c.1137+12076del | Intron (DEL) | VAF 19/141 reads (13%) | called by mutect2, pindel, varscan2
- EPHA8 | c.1315+37C>T | Intron (SNP) | VAF 17/182 reads (9%) | called by muse, mutect2
- HELZ | c.247+65T>G | Intron (SNP) | VAF 24/138 reads (17%) | called by mutect2, varscan2
- PSME3 | c.543-14C>G | Intron (SNP) | VAF 54/242 reads (22%) | called by muse, mutect2, varscan2
